Gene-level copy-number profile of tumor specimen ALCH-ADYK-TTP1-A from ALCHEMIST case ALCH-ADYK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.1 years (24,134 days).
Specimen ALCH-ADYK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c8a3d781-3276-4702-8b56-e27417680424.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADYK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/b81df0c7-2901-4253-9ab6-a4b5b89552b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 18,789; copy number 2: 37,180; copy number 3: 2,668; copy number 4: 135; copy number 5: 66; copy number 6: 29; copy number 7: 10; copy number 8: 20; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:18,605,355–18,611,919, 3 genes: AC023490.1, RN7SKP131, RIMBP3.
- chr22:41,981,304–41,982,217, 1 gene (within-gene range 0–1): Z99716.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 126 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:7,725,801–7,737,095, 3 genes, copy number 6: LINC01871, AC092580.3, AC092580.1.
- chr2:10,783,391–11,151,317, 9 genes, copy number 5 (within-gene range 2–5): PDIA6, RNU7-176P, LINC01954, AC092687.1, AC079587.1, KCNF1, RPL6P4, AC062028.1, C2orf50.
- chr2:11,179,759–11,348,330, 1 gene, copy number 7 (within-gene range 2–7): ROCK2.
- chr2:11,308,025–11,466,177, 6 genes, copy number 7: AIDAP1, PPIAP60, AC099344.1, LINC00570, AC099344.2, E2F6.
- chr2:17,122,841–17,123,140, 1 gene, copy number 5: RN7SKP168.
- chr2:18,547,386–18,548,204, 1 gene, copy number 5: AC079148.1.
- chr2:26,308,173–26,641,366, 6 genes, copy number 5: ADGRF3, SELENOI, DRC1, OTOF, FAM166C, CIB4.
- chr2:30,408,170–30,644,225, 2 genes, copy number 8: AC073255.1, LCLAT1.
- chr2:36,354,749–36,966,536, 9 genes, copy number 5 (within-gene range 3–5): CRIM1-DT, CRIM1, AC007378.1, FEZ2, AC007363.1, VIT, STRN, AC007382.1, RNU6-577P.
- chr2:45,388,680–45,612,165, 2 genes, copy number 5: SRBD1, RN7SL414P.
- chr2:46,392,291–46,670,778, 12 genes, copy number 8: LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247, ATP6V1E2, RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1.
- chr2:53,470,447–53,470,629, 1 gene, copy number 6: AC069157.2.
- chr2:63,892,146–64,453,967, 12 genes, copy number 5–8 (within-gene range 4–8): VPS54, AC012368.2, PELI1, AC012368.1, LINC00309, AC012368.3, AC114752.1, AC114752.2, MIR4433B, MIR4433A, RPL23AP37, LGALSL-DT.
- chr2:67,324,627–67,325,304, 1 gene, copy number 6: AC023115.1.
- chr2:68,023,694–68,826,833, 18 genes, copy number 5: FBXL12P1, C1D, WDR92, PPIAP64, AC017083.3, PNO1, PPP3R1, AC017083.2, AC017083.1, CNRIP1, AC015969.1, PLEK, AC127383.1, FBXO48, APLF, AC130709.1, PROKR1, ARHGAP25.
- chr2:70,607,618–70,900,351, 10 genes, copy number 6: ADD2, AC005234.2, AC005234.1, FIGLA, HMGN2P21, CLEC4F, MOB4P1, CD207, LINC01143, AC007040.3.
- chr2:73,385,758–73,780,157, 10 genes, copy number 6: ALMS1, ALMS1-IT1, AC074008.1, NAT8, ALMS1P1, NAT8B, TPRKB, AC092653.1, AC092653.2, DUSP11.
- chr2:74,513,463–74,893,359, 15 genes, copy number 5: TLX2, DQX1, AUP1, HTRA2, LOXL3, DOK1, M1AP, TOR1BP1, TVP23BP2, SEMA4F, AC007387.2, RPS28P5, AC007387.1, AC019069.1, HK2.
- chr2:77,672,215–77,918,011, 3 genes, copy number 6: AC084149.1, RPL38P2, LINC01851.
- chr2:81,461,358–81,496,327, 2 genes, copy number 7: LINC01815, RNA5SP99.
- chr2:242,175,181–242,175,634, 1 gene, copy number 7: RPL23AP88.
- chr22:18,623,339–18,625,289, 1 gene, copy number 22: SUSD2P2.

Autosomal genes at a single copy (total copy number 1): 17,615. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
